Somatic mutation profile of tumor specimen 0DVBRK from CCDI case PBCMKE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Optic nerve; Age at diagnosis: 11.8 years (4,296 days).
Specimen 0DVBRK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a67ada0-18c3-4ce3-bdaa-32157ccf296c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVBRB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25970a5-1a7a-4449-995d-b779b1cd350c

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYEF2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 62/216 reads (29%) | called by muse, mutect2, varscan2
- GALNT10 | c.969C>T p.A323= | Silent (SNP) | VAF 77/734 reads (10%) | catalogued as rs888200737, COSV51730902; called by muse, mutect2, varscan2
- CSMD2 | c.8312-7472G>A | Intron (SNP) | VAF 62/457 reads (14%) | called by muse, mutect2, varscan2
